Somatic mutation profile of tumor specimen TCGA-EI-6881-01A (aliquot TCGA-EI-6881-01A-11D-1924-10) from TCGA case TCGA-EI-6881, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma in tubulovillous adenoma; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 60.4 years (22,057 days).
Specimen TCGA-EI-6881-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 483e1e3d-fd69-4312-b8f5-28e07aab8b61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EI-6881-10A (Blood Derived Normal), aliquot TCGA-EI-6881-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd1031ca-7321-4d7f-80ac-f8811db58f3b

The open-access MAF lists 109 somatic variants for this specimen: 85 protein-altering or splice-affecting, 24 silent.
By variant classification: Missense Mutation 72, Silent 24, Nonsense Mutation 7, Splice Site 3, Frame Shift Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 71/139 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 32/50 reads (64%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.717A>T p.K239N | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as COSV55296683; called by muse, mutect2, varscan2
- ABCA8 | c.1967C>T p.A656V | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as rs145869753; called by muse, mutect2, varscan2
- APC | c.8126G>T p.G2709V | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV57371302; called by muse, mutect2, varscan2
- APCDD1L | c.960C>A p.D320E | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV64486250, COSV64487649; called by muse, mutect2, varscan2
- CA6 | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as COSV101077613; called by muse, mutect2, varscan2
- CCDC150 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 77/208 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs761071958, COSV55877654; called by muse, mutect2, varscan2
- CCM2 | c.1195A>T p.T399S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as COSV51850667; called by muse, mutect2, varscan2
- CEP104 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs779566424, COSV58215316; called by muse, mutect2, varscan2
- COL19A1 | c.1576C>A p.Q526K | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (1); PolyPhen possibly damaging (0.782); catalogued as COSV59583922; called by muse, mutect2, varscan2
- CSMD1 | c.3055G>C p.A1019P (on ENST00000520002; = p.A1018P on NM_033225.6) | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59367669; called by muse, mutect2, varscan2
- CSMD1 | c.2351A>T p.H784L (on ENST00000520002; = p.H783L on NM_033225.6) | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV59367699; called by muse, mutect2, varscan2
- DMRT1 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.148); catalogued as rs143383634, COSV66523653; called by muse, mutect2, varscan2
- DNAJC13 | c.3122C>T p.T1041I | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV53456091; called by muse, mutect2, varscan2
- DSCAML1 | c.5284G>A p.V1762I (on ENST00000321322; = p.V1702I on NM_020693.4) | Missense Mutation (SNP) | VAF 62/135 reads (46%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.984); catalogued as rs147907435; called by muse, mutect2, varscan2
- DYSF | c.2920G>A p.D974N | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as rs200422222, COSV99249487; called by muse, mutect2, varscan2
- EDRF1 | c.1645G>T p.G549* (on ENST00000356792 / NM_001202438.2; = p.G515* on NM_015608.2) | Nonsense Mutation (SNP) | VAF 34/193 reads (18%) | catalogued as COSV61765789; called by muse, mutect2, varscan2
- FKBP10 | c.1556C>T p.P519L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs140883152; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GFPT2 | c.569A>C p.H190P | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV99517851; called by muse, mutect2, varscan2
- GLMN | c.1689C>A p.F563L | Missense Mutation (SNP) | VAF 160/456 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.164); catalogued as COSV64861351; called by muse, mutect2, varscan2
- GLP2R | c.1429T>A p.C477S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV52328367; called by muse, mutect2, varscan2
- GLYATL2 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.916); catalogued as rs186979803, COSV54849746, COSV99780579; called by muse, mutect2, varscan2
- GRIK2 | c.2653G>T p.V885L | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV59761815; called by muse, mutect2, varscan2
- HOXB13 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1567701707, COSV51706959; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ICE1 | c.1640A>C p.E547A | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.086); catalogued as COSV56830425; called by muse, mutect2
- IGLV3-9 | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.095); catalogued as rs780689649; called by muse, mutect2, varscan2
- IQGAP2 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV57179730; called by muse, mutect2, varscan2
- KLRC1 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 17/266 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.497); catalogued as rs1415053226, COSV61724770, COSV61725066; called by muse, mutect2
- LAMA3 | c.8242G>A p.V2748I (on ENST00000313654 / NM_198129.4; = p.V1139I on NM_000227.6) | Missense Mutation (SNP) | VAF 63/107 reads (59%) | SIFT tolerated (0.2); PolyPhen benign (0.048); catalogued as rs148548958; called by muse, mutect2, varscan2
- MAP4K3 | c.1240G>C p.D414H | Missense Mutation (SNP) | VAF 51/251 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV55717010; called by muse, mutect2, varscan2
- MYO3A | c.1897G>T p.E633* | Nonsense Mutation (SNP) | VAF 18/90 reads (20%) | catalogued as COSV56344325; called by muse, mutect2, varscan2
- MYORG | c.1567T>C p.S523P | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99898739; called by muse, mutect2, varscan2
- NCBP1 | c.604T>A p.Y202N | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64317337; called by muse, mutect2, varscan2
- NCOA3 | c.3637C>T p.Q1213* | Nonsense Mutation (SNP) | VAF 26/51 reads (51%) | catalogued as COSV59065874; called by muse, mutect2, varscan2
- NLRX1 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as rs199476042, COSV52708360; ClinVar: not provided; called by muse, mutect2, varscan2
- NOVA2 | c.609C>A p.D203E | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV54359268; called by muse, mutect2
- NRXN3 | c.3080G>A p.R1027H (on ENST00000335750 / NM_001330195.2; = p.R654H on NM_004796.6) | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs368490229; called by muse, mutect2, varscan2
- OBSCN | c.11050C>T p.R3684C | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as rs201875033, COSV99476790; called by muse, varscan2
- PDE1B | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54495373; called by muse, mutect2, varscan2
- PIGG | c.1689G>T p.L563F (on ENST00000453061 / NM_001127178.3; = p.L555F on NM_017733.4) | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as COSV56320711, COSV56322051; called by muse, mutect2, varscan2
- PILRB | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60335947; called by muse, mutect2, varscan2
- PLCE1 | c.4682C>A p.S1561Y | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.312); catalogued as COSV53366513; called by muse, mutect2, varscan2
- PMP2 | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 72/189 reads (38%) | catalogued as rs375558516; called by muse, mutect2, varscan2
- PNPLA7 | c.3443C>T p.T1148M | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53004945; called by muse, mutect2, varscan2
- PNPLA7 | c.118+1G>A p.X40_splice | Splice Site (SNP) | VAF 19/53 reads (36%) | catalogued as rs776015129, COSV53004958; called by muse, mutect2, varscan2
- POLA1 | c.759C>G p.D253E | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.64); catalogued as COSV66889808; called by muse, mutect2
- PRKCG | c.1482C>G p.I494M | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99669255; called by muse, mutect2, varscan2
- PTCH2 | c.2155C>T p.R719W | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs200355030, COSV100942187; called by muse, mutect2, varscan2
- PTGER3 | c.1207G>A p.V403M | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.157); catalogued as rs568020055, COSV100656960; called by muse, mutect2, varscan2
- RALGAPB | c.3281C>T p.T1094M | Missense Mutation (SNP) | VAF 98/186 reads (53%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs761192665, COSV99484519; called by muse, mutect2, varscan2
- RPTN | c.2254C>G p.Q752E | Missense Mutation (SNP) | VAF 353/916 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as COSV60168574; called by muse, mutect2, varscan2
- RRAD | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.174); catalogued as COSV55338929; called by muse, mutect2, varscan2
- RTKN2 | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 65/266 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV65681236; called by muse, mutect2, varscan2
- SCN9A | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs775461240, COSV57604465; called by muse, mutect2, varscan2
- SH3GLB2 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs990971801, COSV65330520; called by muse, mutect2, varscan2
- SH3TC2 | c.436C>A p.L146I | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60466741; called by muse, mutect2, varscan2
- SHANK1 | c.5483C>T p.P1828L | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); catalogued as rs1357674190, COSV53259498; called by muse, mutect2, varscan2
- SHCBP1 | c.1046C>T p.T349M | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs199982006, COSV57649751; called by muse, mutect2, varscan2
- SLC1A6 | c.1663C>T p.R555W | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1353279163, COSV55673227; called by muse, mutect2, varscan2
- SLC6A16 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 100/284 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.248); catalogued as COSV60027579; called by muse, mutect2, varscan2
- SMTNL1 | c.1171G>A p.A391T (on ENST00000399154; = p.A428T on NM_001105565.2) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs778534246, COSV67700572; called by muse, mutect2, varscan2
- SNTG2 | c.1145A>G p.E382G | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV58001014; called by muse, mutect2, varscan2
- SOCS6 | c.814G>T p.D272Y | Missense Mutation (SNP) | VAF 98/164 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); catalogued as COSV101205683; called by muse, varscan2
- SPATA31E1 | c.1513C>T p.H505Y | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs766099083, COSV57794346; called by muse, mutect2, varscan2
- SPTA1 | c.2938C>A p.Q980K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as rs539524312, COSV63757764; called by muse, mutect2, varscan2
- TAP2 | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs770778501, COSV66498371; called by muse, mutect2, varscan2
- TBC1D1 | c.882G>A p.T294= | Splice Region (SNP) | VAF 70/133 reads (53%) | catalogued as COSV54725300, COSV99791407; called by muse, mutect2, varscan2
- TBXAS1 | c.1094A>T p.E365V | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.865); catalogued as COSV54952082; called by muse, mutect2, varscan2
- TENM2 | c.830A>T p.N277I (on ENST00000518659 / NM_001122679.2; = p.N86I on NM_001080428.3) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.773); catalogued as COSV69138595; called by muse, mutect2, varscan2
- TIGIT | c.310G>T p.G104W | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67329334; called by muse, mutect2, varscan2
- TMEM41B | c.353T>A p.F118Y | Missense Mutation (SNP) | VAF 18/203 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV55156490; called by muse, mutect2
- TOM1L2 | c.778-1G>C p.X260_splice (on ENST00000379504 / NM_001350333.2; = p.X210_splice on NM_001033551.3) | Splice Site (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100541115; called by muse, mutect2
- TRIM62 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs762636288, COSV52220373; called by muse, mutect2, varscan2
- TTN | c.68236A>T p.T22746S (on ENST00000591111; = p.T15322S on NM_003319.4) | Missense Mutation (SNP) | VAF 14/110 reads (13%) | PolyPhen possibly damaging (0.572); catalogued as COSV60271890; called by muse, mutect2, varscan2
- TTN | c.47980C>T p.R15994* (on ENST00000591111; = p.R8570* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 20/186 reads (11%) | catalogued as COSV60271900; called by muse, mutect2
- UBA1 | c.465C>A p.F155L | Missense Mutation (SNP) | VAF 44/53 reads (83%) | SIFT tolerated (0.62); PolyPhen benign (0.411); catalogued as COSV60114907; called by muse, mutect2, varscan2
- VGF | c.1723C>T p.H575Y | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs761504889; called by muse, mutect2, varscan2
- VPS13D | c.4805C>A p.T1602N | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV50668735; called by muse, mutect2, varscan2
- VSTM1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753821114, COSV58076284; called by muse, mutect2, varscan2
- VWA8 | c.2363del p.N788Tfs*51 | Frame Shift Del (DEL) | VAF 169/408 reads (41%) | catalogued as rs1249188820; called by mutect2, pindel, varscan2
- ZNF282 | c.1774C>T p.H592Y | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50482590; called by muse, mutect2, varscan2
- APC | c.4483del p.S1495Vfs*12 | Frame Shift Del (DEL) | VAF 46/95 reads (48%) | called by mutect2, pindel, varscan2
- PLCXD2 | c.163+2dup p.X55_splice | Splice Site (INS) | VAF 12/44 reads (27%) | called by mutect2, pindel, varscan2
- CD1C | c.639C>A p.R213= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV63807313; called by mutect2, varscan2
- COLGALT2 | c.1119C>T p.V373= | Silent (SNP) | VAF 71/178 reads (40%) | catalogued as rs775464061, COSV62298932, COSV62299992; called by muse, mutect2, varscan2
- DNAH17 | c.6951G>A p.P2317= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as rs577641893, COSV67759739; called by muse, mutect2, varscan2
- EPHA1 | c.2073C>A p.V691= | Silent (SNP) | VAF 34/71 reads (48%) | catalogued as COSV51975090; called by muse, mutect2, varscan2
- EXOC2 | c.2442C>T p.F814= | Silent (SNP) | VAF 31/97 reads (32%) | catalogued as COSV57870423; called by muse, mutect2, varscan2
- GRB14 | c.1287A>T p.T429= | Silent (SNP) | VAF 50/119 reads (42%) | catalogued as COSV55741926; called by muse, mutect2
- IBSP | c.516C>T p.N172= | Silent (SNP) | VAF 81/171 reads (47%) | catalogued as rs752731584, COSV56894484; called by muse, mutect2, varscan2
- KLHL1 | c.90C>T p.G30= | Silent (SNP) | VAF 58/67 reads (87%) | catalogued as rs764920556, COSV64780027; called by muse, mutect2, varscan2
- KRT34 | c.1308T>C p.N436= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV67450488; called by muse, mutect2, varscan2
- LIG4 | c.1485G>A p.E495= | Silent (SNP) | VAF 100/108 reads (93%) | catalogued as COSV63597819; called by muse, mutect2, varscan2
- NEXMIF | c.4464C>T p.S1488= | Silent (SNP) | VAF 61/90 reads (68%) | catalogued as rs189355247, COSV50078006; called by muse, mutect2, varscan2
- NOL8 | c.189G>A p.A63= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as rs201912608, COSV62637128; called by muse, mutect2, varscan2
- NOX4 | c.939G>A p.S313= | Silent (SNP) | VAF 96/255 reads (38%) | catalogued as rs765167454, COSV54461757; called by muse, varscan2
- OXSR1 | c.255A>G p.K85= | Silent (SNP) | VAF 58/140 reads (41%) | catalogued as COSV61260099; called by muse, mutect2, varscan2
- PCDH15 | c.4800C>T p.N1600= (on ENST00000644397 / NM_001354429.2; = p.N1542= on NM_001142771.2) | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as rs750530478, COSV64682816; called by muse, mutect2, varscan2
- PPP2CA | c.408A>G p.K136= | Silent (SNP) | VAF 40/175 reads (23%) | catalogued as COSV51538842; called by muse, mutect2, varscan2
- PPP2R1A | c.84C>T p.R28= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs1430789109, COSV59047388; called by muse, mutect2, varscan2
- PREX1 | c.2883G>A p.P961= | Silent (SNP) | VAF 38/68 reads (56%) | catalogued as rs368665525, COSV64255201; called by muse, mutect2, varscan2
- PSMD1 | c.1440C>A p.G480= | Silent (SNP) | VAF 19/109 reads (17%) | catalogued as rs1256015599, COSV100433583, COSV58082392; called by muse, mutect2, varscan2
- PTPRG | c.591C>T p.I197= | Silent (SNP) | VAF 63/335 reads (19%) | catalogued as rs374241237, COSV55658295; called by muse, mutect2, varscan2
- SPAG8 | c.915G>A p.E305= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV52415439; called by muse, mutect2, varscan2
- TBC1D14 | c.318G>A p.A106= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as rs758663978, COSV68986679; called by muse, mutect2, varscan2
- TMPRSS13 | c.1194C>T p.A398= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs745923344, COSV70627374; called by muse, mutect2, varscan2
- ZNF521 | c.507C>T p.T169= | Silent (SNP) | VAF 132/213 reads (62%) | catalogued as rs370530167, COSV100833349; called by muse, mutect2, varscan2
